Somatic mutation profile of tumor specimen TARGET-10-PAPCRU-03A (aliquot TARGET-10-PAPCRU-03A-01D) from TARGET case TARGET-10-PAPCRU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,435 days).
Specimen TARGET-10-PAPCRU-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6506a88e-39cf-456b-9969-8206a2343d9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCRU-10A (Blood Derived Normal), aliquot TARGET-10-PAPCRU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/188b4427-60f9-4855-be96-6cac820df50b

The open-access MAF lists 73 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 17, Intron 4, RNA 4, 5'Flank 3, 3'UTR 2, 5'UTR 2, Splice Site 1, Frame Shift Del 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AREL1 | c.1002T>G p.D334E | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771440340; called by muse, mutect2, varscan2
- CREBBP | c.4504T>G p.W1502G | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52114397, COSV52134695; called by muse, mutect2, varscan2
- EHBP1L1 | c.701C>G p.A234G | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1197927901; called by muse, mutect2, varscan2
- F13A1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs144411857, COSV53569944; called by muse, mutect2, varscan2
- FRMPD3 | c.3962G>A p.G1321E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as rs1237716704; called by muse, mutect2, varscan2
- HNF4G | c.677C>T p.P226L (on ENST00000354370 / NM_001330561.2; = p.P273L on NM_004133.5) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1209691575; called by muse, mutect2, varscan2
- KCNQ5 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV100573256; called by muse, mutect2, varscan2
- KRT76 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1344947595; called by muse, mutect2
- MEDAG | c.671T>G p.L224W | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs943025022; called by muse, mutect2, varscan2
- MLIP | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1468287405; called by muse, mutect2, varscan2
- NAA11 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.285); catalogued as COSV104379576, COSV54515835; called by muse, mutect2, varscan2
- NPY4R | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs868947368, COSV65397504; called by muse, mutect2, varscan2
- OR8B4 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); catalogued as rs755381467, COSV100635732, COSV100635830; called by muse, mutect2, varscan2
- PATJ | c.5177G>A p.R1726Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.923); catalogued as rs747934422; called by muse, mutect2, varscan2
- PKHD1 | c.6737T>C p.M2246T | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs1312358253; called by muse, mutect2, varscan2
- TBX20 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1304347935; called by muse, mutect2, varscan2
- TTN | c.6952C>T p.R2318C (on ENST00000591111; = p.R2272C on NM_003319.4) | Missense Mutation (SNP) | VAF 35/159 reads (22%) | PolyPhen probably damaging (0.998); catalogued as rs1487336498, COSV59955208; called by muse, mutect2, varscan2
- VEGFC | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as rs201028890, COSV54608824; called by muse, mutect2, varscan2
- ZDHHC11 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV52062818; called by muse, mutect2, varscan2
- C4A | c.3194C>T p.S1065F | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYP2D6 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- DCAF8L2 | c.1627A>C p.T543P | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DDX19B | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FBXO24 | c.1652C>T p.A551V (on ENST00000241071 / NM_033506.3; = p.A589V on NM_012172.5) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- H4C6 | c.50_56del p.K17Ifs*26 | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | called by mutect2, pindel, varscan2
- KCNF1 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLF15 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- LAMA2 | c.2185G>A p.G729R | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPAR6 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP1 | c.3605-1G>A p.X1202_splice (on ENST00000404816 / NM_206943.4; = p.X876_splice on NM_000627.4) | Splice Site (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- MGST1 | c.126+5G>A | Splice Region (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- MSR1 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OPCML | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PAK5 | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF20L1 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R13L | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SH3GL3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- THAP4 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLN1 | c.713_714insGGC p.F238delinsLA | In Frame Ins (INS) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- WIZ | c.1904C>T p.S635F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZBBX | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS3 | c.255G>A p.T85= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV99710650; called by muse, mutect2, varscan2
- ANOS1 | c.1056G>A p.T352= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs751290377; called by muse, mutect2, varscan2
- ASXL1 | c.1578C>T p.S526= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV60104712; called by muse, mutect2, varscan2
- C4orf54 | c.4419C>T p.I1473= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- CSMD3 | c.9774C>T p.I3258= (on ENST00000297405 / NM_001363185.1; = p.I3089= on NM_052900.3) | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- CT83 | c.210C>T p.F70= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as rs1556695221; called by muse, mutect2, varscan2
- EMX2 | c.507G>A p.L169= | Silent (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- EYS | c.6225C>T p.S2075= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs1272738105, COSV65546160; called by muse, mutect2, varscan2
- FLT1 | c.3954C>T p.I1318= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as rs372529662; called by muse, mutect2, varscan2
- IRS2 | c.3249G>T p.P1083= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV65480339; called by muse, mutect2
- OR56A3 | c.51C>T p.L17= | Silent (SNP) | VAF 46/163 reads (28%) | called by muse, mutect2, varscan2
- PLCL1 | c.1350A>C p.S450= | Silent (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- SH2B1 | c.1656C>T p.F552= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- SLC4A8 | c.3090G>A p.E1030= | Silent (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- STKLD1 | c.861G>A p.T287= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs1554776633; called by muse, mutect2, varscan2
- ULBP3 | c.705C>T p.I235= | Silent (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2, varscan2
- WNK2 | c.2598G>A p.G866= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- AC004899.2 | chr7:48847206 T>C | 5'Flank (SNP) | VAF 66/209 reads (32%) | catalogued as rs1168358502; called by muse, mutect2, varscan2
- AC124067.2 | n.379C>T | RNA (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.808-76T>C | Intron (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- BBS5 | c.142+52T>C | Intron (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- KANK4 | c.1901-65C>T | Intron (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- MED6 | chr14:70600663 C>T | 5'Flank (SNP) | VAF 8/61 reads (13%) | catalogued as rs1003915665, COSV56450208; called by muse, mutect2, varscan2
- MTHFR | c.*2574C>T | 3'UTR (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- NAA20 | c.53+482C>T | Intron (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- RARRES2P7 | n.263C>T | RNA (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- RARRES2P7 | n.262C>T | RNA (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159082 G>A | 5'Flank (SNP) | VAF 11/33 reads (33%) | catalogued as rs1349403478; called by muse, mutect2, varscan2
- SIGLEC10 | c.-18T>A | 5'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2
- SLC45A4 | c.-4G>T | 5'UTR (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- TCEAL2 | c.*44G>A | 3'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as rs185783343; called by muse, varscan2
- TMEM75 | n.761G>A | RNA (SNP) | VAF 45/196 reads (23%) | called by muse, mutect2, varscan2
